Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A0ZV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A0ZV-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS:

A. Uterus, hysterectomy: FIGO grade II (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a diffuse mass (4.0 x 2.8 x 1.6 cm) in the fundus involving the anterior and posterior uterine wall. The tumor invades 0.4 cm into the myometrium (total myometrial thickness, 1.4 cm). The lower uterine segment is uninvolved. The endocervical mucosa shows focal superficial involvement by tumor, which does not involve the cervical connective tissue stroma. Lymphovascular space invasion is not identified. The resection margins are negative for tumor. There is a single subserosal leiomyoma (1.3 cm in greatest dimension). [AJCC pT1bN0MX]

B, C. Ovary and fallopian tube, right and left, bilateral salpingo-oophorectomy: Without diagnostic abnormality, bilaterally.

D. Lymph nodes, left pelvic, lymphadenectomy: Multiple (12) left pelvic lymph nodes are negative for tumor.

E. Lymph nodes, right pelvic, lymphadenectomy: Multiple (11) right pelvic lymph nodes are negative for tumor.

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

[page 2 of 3]
GROSS DESCRIPTION:

A. Received fresh labeled "uterus" is a 71.0 gram uterus with unremarkable cervix. There is a 0.8 x 0.8 x 0.5 cm soft red-tan mass in the endocervical canal. The uterine serosa is smooth. There is a 4.0 x 2.8 x 1.6 cm mass in the fundus of the endometrial cavity which grossly appears to invade superficially into the 1.4 cm thick myometrium. There is a 0.8 x 0.8 x 0.8 cm hemorrhagic focus in the endocervical canal at the os. There is a single subserosal leiomyoma (1.3 cm in greatest dimension). Representative sections are submitted.

B. Received fresh labeled "right fallopian tube and ovary" is a 3.0 x 2.3 x 1.1 cm ovary with a 5.3 x 0.6 cm attached fallopian tube. The ovary has a smooth outer surface and a solid cut surface. Representative sections submitted.

C. Received fresh labeled "left fallopian tube and ovary" is a 3.0 x 1.7 x 1.0 cm ovary with a 5.5 x 0.6 cm attached fallopian tube. The ovary has a smooth outer surface and a solid cut surface. Representative sections submitted.

D. Received fresh labeled "left pelvic lymph nodes" is a 6.0 x 5.0 x 2.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

E. Received fresh labeled "right pelvic nodes" is a 6.0 x 4.0 x 1.8

[page 3 of 3]
cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

BLOCK SUMMARY:

Part A: Uterus

- 1 6:00 cervix
- 2 Lower uterine segment
- 3 Post endometrium-1
- 4 Post endometrium-2
- 5 Post endometrium-3
- 6 Post endometrium-4
- 7 Post endometrium-5
- 8 Ant endometrium

Part B: Right fallopian tube and ovary

- 1 Right ovary
- 2 Right fallopian tube

Part C: Left fallopian tube and ovary

- 1 Left ovary
- 2 Left fallopian tube

Part D: Left Pelvic Lymph Nodes

- 1 Lt pelvic lns-4 (D1)
- 2 Lt pelvic lns-4 (D2)
- 3 Lt pelvic ln-1of2 (D3)
- 4 Lt pelvic ln-2of2 (D3)
- 5 Lt pelvic ln-1 (D4)
- 6 Lt pelvic ln-1of3 (D5)
- 7 Lt pelvic ln-2of3 (D5)
- 8 Lt pelvic ln-3of3 (D5)

Part E: Right Pelvic Nodes

- 1 Rt pelvic lns-5 (E1)
- 2 Rt pelvic lns-4 (E2)
- 3 Rt pelvic lns-2 (E3)
- 4 Rt pelvic ln-1of3 (E4)
- 5 Rt pelvic ln-2of3 (E4)
- 6 Rt pelvic ln-3of3 (E4)

HIFAA Discrepancy		

Source: NCI Genomic Data Commons file 6af9fc17-fc50-4fe0-b06b-523d0a09dc6f (TCGA-D1-A0ZV.C9AE2762-705F-4061-B3B6-325426D0C0C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).